Somatic mutation profile of tumor specimen TCGA-EP-A3JL-01A (aliquot TCGA-EP-A3JL-01A-11D-A20W-10) from TCGA case TCGA-EP-A3JL, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 76.3 years (27,886 days).
Specimen TCGA-EP-A3JL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df4e286e-4623-48ec-af10-71c5307e2dc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EP-A3JL-10A (Blood Derived Normal), aliquot TCGA-EP-A3JL-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/584b9d0d-d485-4587-bb58-df2e639654fa

The open-access MAF lists 95 somatic variants for this specimen: 77 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 17, Splice Site 4, Nonsense Mutation 3, In Frame Del 2, Frame Shift Del 2, Frame Shift Ins 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1161T>A p.N387K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868651538, COSV62688055, COSV62689041; called by muse, mutect2, varscan2
- ACOX1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV53133479; called by muse, mutect2, varscan2
- ADD3 | c.1183C>G p.R395G | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1417018729, COSV53322523; called by muse, mutect2, varscan2
- ADGRV1 | c.7256C>A p.P2419H | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67986030; called by muse, mutect2, varscan2
- ALOX5 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.839); catalogued as rs994081039, COSV65552550; called by muse, mutect2, varscan2
- ANKRD24 | c.3419G>C p.R1140T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV53671138; called by muse, mutect2, varscan2
- ARG1 | c.895A>G p.I299V | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51581067; called by muse, mutect2, varscan2
- BARD1 | c.452G>A p.S151N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53612369; called by mutect2, varscan2
- BPTF | c.512A>G p.D171G | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1284339360, COSV58837802; called by muse, mutect2, varscan2
- CCDC191 | c.2078A>G p.Q693R | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV55672479; called by muse, mutect2, varscan2
- CD200R1L | c.88A>G p.N30D | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.628); catalogued as COSV68004324; called by muse, mutect2, varscan2
- CD300C | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 33/107 reads (31%) | catalogued as COSV58170531; called by muse, mutect2, varscan2
- CDH13 | c.1934G>T p.S645I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV51823427; called by muse, mutect2, varscan2
- CDH18 | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as rs755435892, COSV56915596; called by muse, mutect2, varscan2
- CROCC | c.735G>T p.Q245H | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV65012256; called by muse, mutect2, varscan2
- DCC | c.2687A>G p.K896R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.651); catalogued as COSV59104744; called by muse, mutect2, varscan2
- DNER | c.2064C>A p.S688R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV59167286; called by muse, mutect2, varscan2
- DYRK1A | c.1069G>T p.G357* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as rs1555985724, COSV58294189; called by muse, mutect2, varscan2
- EFNB2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV55364980; called by muse, mutect2, varscan2
- ELK4 | c.640A>T p.I214F | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV56985025; called by muse, mutect2, varscan2
- ENAM | c.1354A>G p.K452E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs751890482, COSV68536054; called by muse, mutect2, varscan2
- ERBB4 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53536088; called by muse, mutect2, varscan2
- EVPL | c.2137T>A p.F713I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV56911563; called by muse, mutect2
- FAM120A | c.2396G>T p.W799L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52905505; called by muse, mutect2, varscan2
- FAT4 | c.7272G>T p.L2424F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV58687518; called by muse, mutect2, varscan2
- GAB4 | c.899C>A p.T300N | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.433); catalogued as COSV68753938; called by muse, mutect2, varscan2
- GADL1 | c.1251-1G>A p.X417_splice | Splice Site (SNP) | VAF 14/49 reads (29%) | catalogued as COSV56979245; called by muse, mutect2, varscan2
- GRIA1 | c.2112G>A p.M704I | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV53590043; called by muse, mutect2, varscan2
- H2AC20 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.92); catalogued as COSV58612053; called by muse, mutect2, varscan2
- IHO1 | c.1248G>A p.M416I | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1198040115, COSV56507903; called by muse, mutect2, varscan2
- KMT2B | c.4837A>G p.I1613V | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs1370214169, COSV55861794; called by muse, mutect2, varscan2
- LILRB3 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.892); catalogued as rs746656873; called by muse, varscan2
- LILRB4 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as COSV54405497; called by muse, mutect2, varscan2
- MMRN1 | c.1514C>A p.S505Y | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53337798; called by muse, mutect2, varscan2
- MNS1 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV53068480; called by muse, mutect2, varscan2
- MS4A15 | c.641G>A p.S214N (on ENST00000405633 / NM_001098835.2; = p.S121N on NM_152717.3) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.045); catalogued as rs779694586, COSV61961260; called by muse, mutect2, varscan2
- MUC16 | c.41507G>T p.G13836V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1309788182, COSV66692365; called by muse, mutect2, varscan2
- MYH15 | c.256-2A>G p.X86_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as rs773774527, COSV56310989; called by muse, mutect2, varscan2
- NXPH2 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV55643183; called by muse, mutect2, varscan2
- OGFOD3 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.446); catalogued as COSV57341239; called by muse, mutect2, varscan2
- OR10Q1 | c.589A>T p.I197F | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV57470609; called by muse, mutect2, varscan2
- PCDH11Y | c.2888A>G p.D963G (on ENST00000400457 / NM_032973.2; = p.D952G on NM_032971.3) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.173); catalogued as COSV53081492; called by muse, mutect2, varscan2
- PER1 | c.1030A>G p.I344V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.651); catalogued as rs769554705, COSV57919681; called by muse, mutect2, varscan2
- PGAM5 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1448250757, COSV58202167; called by muse, mutect2, varscan2
- PIGM | c.5G>C p.G2A | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV63635691; called by muse, mutect2, varscan2
- POMC | c.206C>G p.P69R | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as CD064616, COSV53034985; called by muse, mutect2, varscan2
- RAD1 | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 105/167 reads (63%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.665); catalogued as COSV57715230; called by muse, mutect2, varscan2
- RASD2 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV53352592; called by muse, mutect2, varscan2
- RYR2 | c.7041G>A p.M2347I | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0.026); catalogued as COSV63687579; called by muse, mutect2, varscan2
- SAMSN1 | c.586T>C p.C196R | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.632); catalogued as COSV53471807; called by muse, mutect2, varscan2
- SEC24B | c.202T>C p.S68P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.986); catalogued as COSV99494390; called by muse, mutect2
- SF3B1 | c.1727T>C p.V576A | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV59209745; called by muse, mutect2, varscan2
- SF3B3 | c.2134G>A p.V712I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as COSV56787900; called by mutect2, varscan2
- SFMBT2 | c.494C>A p.S165* | Nonsense Mutation (SNP) | VAF 26/160 reads (16%) | catalogued as COSV62810096, COSV62813759; called by muse, mutect2, varscan2
- SFMBT2 | c.493T>A p.S165T | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.13); catalogued as COSV62810104; called by muse, mutect2, varscan2
- SGPP2 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.034); catalogued as COSV58329262, COSV58332333; called by muse, mutect2, varscan2
- SHC1 | c.679T>G p.F227V (on ENST00000368445 / NM_183001.5; = p.F117V on NM_003029.5) | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV63534831; called by muse, mutect2, varscan2
- SLC39A4 | c.413C>T p.P138L (on ENST00000301305 / NM_001374839.1; = p.P113L on NM_017767.3) | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs781929804, COSV52779064; called by muse, mutect2
- SLC44A5 | c.1212A>T p.K404N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.826); catalogued as COSV100901399, COSV63765748; called by muse, mutect2, varscan2
- SMARCAD1 | c.2063G>T p.R688I | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV62774544; called by muse, mutect2, varscan2
- SPESP1 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV52989393; called by muse, mutect2, varscan2
- SPTA1 | c.4529A>G p.E1510G | Missense Mutation (SNP) | VAF 13/292 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV63753875; called by muse, mutect2
- STARD13 | c.1363C>G p.R455G (on ENST00000336934 / NM_001243476.3; = p.R337G on NM_052851.3) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55229443; called by muse, mutect2, varscan2
- TBC1D21 | c.385A>C p.I129L | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771171857, COSV55995406; called by muse, mutect2, varscan2
- TMF1 | c.2180G>T p.R727L | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68374404, COSV68375954; called by muse, mutect2, varscan2
- UBE2N | c.21G>T p.R7S | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58867870; called by muse, mutect2, varscan2
- USP47 | c.2482C>G p.L828V (on ENST00000399455 / NM_001372095.1; = p.L740V on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV60464132; called by muse, mutect2, varscan2
- VWA3A | c.3263C>A p.S1088Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55390000; called by muse, mutect2, varscan2
- WDR24 | c.1940C>T p.S647L (on ENST00000248142; = p.S517L on NM_032259.4) | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as COSV50197747; called by muse, mutect2, varscan2
- ZCCHC7 | c.611-1G>A p.X204_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV60957597; called by mutect2, varscan2
- ALB | c.351dup p.Q118Tfs*4 | Frame Shift Ins (INS) | VAF 16/74 reads (22%) | called by mutect2, pindel, varscan2
- APOB | c.7279_7283del p.L2427Vfs*3 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- COL18A1 | c.4290_4306del p.G1431Wfs*65 (on ENST00000359759 / NM_130444.3; = p.G1196Wfs*65 on NM_030582.4) | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel
- GALNT3 | c.1517_1524+8del p.X506_splice | Splice Site (DEL) | VAF 16/74 reads (22%) | called by mutect2, pindel
- NFKBIA | c.608_616del p.V203_L205del | In Frame Del (DEL) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.1478C>G p.P493R | Missense Mutation (SNP) | VAF 95/171 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- PRG4 | c.2514_2537del p.K840_P847del | In Frame Del (DEL) | VAF 30/236 reads (13%) | called by mutect2, pindel, varscan2
- ACTR1A | c.303T>G p.T101= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV64023397; called by muse, mutect2, varscan2
- CD2 | c.987C>A p.P329= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV65644295; called by muse, mutect2, varscan2
- CD300C | c.507C>A p.P169= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as COSV58170537; called by muse, mutect2, varscan2
- CRTC3 | c.495T>C p.A165= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV51596972; called by muse, mutect2, varscan2
- CYB5RL | c.828G>A p.L276= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99839201; called by muse, varscan2
- DNAH5 | c.7974T>C p.D2658= | Silent (SNP) | VAF 106/203 reads (52%) | catalogued as COSV54227754; called by muse, mutect2, varscan2
- FREM2 | c.426C>A p.G142= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV54839089; called by muse, mutect2, varscan2
- KLK8 | c.84A>T p.A28= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV51592144; called by muse, mutect2, varscan2
- LDLRAD4 | c.648T>C p.S216= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs1450631249, COSV63337671; called by muse, mutect2, varscan2
- PDK4 | c.450C>T p.V150= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as rs769225726, COSV50011086; called by muse, mutect2, varscan2
- PSRC1 | c.585G>T p.S195= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV64021290; called by muse, mutect2, varscan2
- TECTA | c.1176C>T p.I392= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV50713582; called by muse, mutect2, varscan2
- TRPC4 | c.2541A>G p.L847= (on ENST00000379705 / NM_016179.4; = p.L852= on NM_003306.3) | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV59001249; called by muse, mutect2, varscan2
- TTLL4 | c.3495T>C p.S1165= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as rs1360179486, COSV51436598; called by muse, mutect2, varscan2
- VWA3A | c.3264C>A p.S1088= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100241351; called by muse, mutect2, varscan2
- ZBTB10 | c.1416A>G p.P472= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV66947612; called by muse, mutect2, varscan2
- ZMYM5 | c.948A>G p.T316= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV61988575; called by muse, mutect2, varscan2
- UBTFL2 | n.243G>A | RNA (SNP) | VAF 30/186 reads (16%) | called by muse, mutect2, varscan2
